Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABO, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABO-01A (Primary Tumor).

[page 1 of 3]
Surgery date: Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

DIAGNOSIS:

A. Liver, right lobe, biopsy: Scant liver parenchyma with capsular fibrosis. Rare cluster of atypical cells of uncertain significance.

B. Lymph node, common hepatic, biopsy: Involved by metastatic adenocarcinoma.

C. Common hepatic duct, margin, excision: Negative for tumor.

D. Pancreatic body, margin, excision: Intraductal papillary mucinous neoplasm with high-grade dysplasia, present in the pancreatic duct. No invasive carcinoma.

E. Portal vein, adventitia, biopsy: Negative for tumor.

F. Head pancreas, gallbladder, duodenum, common bile duct, portion jejunum, Whipple resection: Invasive moderately differentiated ductal adenocarcinoma on a background of extensive intraductal papillary mucinous neoplasm with high-grade dysplasia, forming a solid 4.6 x 2.3 x 2.0 cm mass located in the pancreatic head. The tumor extends beyond pancreas to involve the peripancreatic soft tissue. Perineural invasion is present. The uncinate margin tissue shows metastatic adenocarcinoma to a lymph node with soft tissue extension. The tumor is 0.1 cm from the portal vein groove. The patient has had no prior treatment. Multiple (7 of 15) regional lymph nodes are involved by metastatic metastatic adenocarcinoma. The gallbladder shows mild chronic cholecystitis.

G. Pancreatic body, new margin, excision: Negative for invasive adenocarcinoma. Intraductal papillary mucinous neoplasm with low-grade dysplasia.

AJCC stage (with available surgical material): pT3N1 (7th edition).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). A revised report will be issued to document the final interpretation after review of the Hematoxylin and Eosin (H&E) permanent sections.

Interpreted by:
Report electronically signed by
Transcribed by:

ICD-O-3
Adenocarcinoma duct NAS
Site: Pancreas head
850013
C25.0
JTD 5/5/14

[page 2 of 3]
ADDENDUM:

Frozen section interpretation has been confirmed by Hematoxylin and Eosin (H&E) permanent section review.

GROSS DESCRIPTION:

A. Received fresh labeled "right lobe liver biopsy" is a 1.2 x 0.3 x 0.3 cm aggregate of tan-pink tissue. All submitted. Grossed by

B. Received fresh labeled "common hepatic lymph node" is a 1.7 x 1.2 x 0.3 cm lymph node. All submitted. Grossed by

C. Received fresh labeled "common hepatic duct margin" is a 1.5 x 0.5 x 0.3 cm fragment of pink-tan soft tissue with orientation. Margin submitted. Grossed by

D. Received fresh labeled "pancreatic body margin" is a 3.0 x 2.0 x 0.5 cm portion of pink-tan soft tissue with orientation. Margin submitted. Grossed by

E. Received fresh labeled "adventitia tissue portal vein" is a 0.3 x 0.1 x 0.1 cm fragment of pink tissue. All submitted. Grossed by

F. Received fresh labeled "head pancreas, gallbladder, duodenum, common bile duct, portion jejunum" is a Whipple specimen consisting of 34.0 cm in length portion of duodenum, 6.0 x 5.0 x 3.0 cm portion of pancreas, 9.3 x 4.2 x 2.6 cm gallbladder. The pancreatic uncinate margin is inked yellow and shaved, the portal vein groove is inked black and submitted perpendicularly. There is a 4.6 x 2.3 x 2.0 cm diffusely infiltrative mass within the pancreas, 0.1 cm from the portal vein groove margin. The mass is confined to the pancreas. The gallbladder contains no choleliths. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Research tissue collected,
Grossed by

G. Received fresh labeled "new pancreatic body margin" is a 3.1 x 2.0 x 0.7 cm portion of pancreatic tissue with orientation. All submitted. Grossed by

BLOCK SUMMARY:

Part A: Right lobe liver biopsy
1 Rt lobe liver bx

Part B: Common hepatic lymph node

[page 3 of 3]
1 Comm hepatic LN 1(B1)

Part C: Common hepatic duct margin

1 Comm hepatic duct margin

Part D: Pancreatic body margin

1 Pancreatic body margin 1

2 Pancreatic body margin 2

Part E: Adventitia tissue portal vein

1 Advenitia tissue portal vein

Part F: Head pancrea, gallbladder, duodenum, common bile duct, portion jejunum

1 Uncinate margin 1

2 Uncinate margin 1

3 Uncinate margin 2

4 Uncinate margin 2

5 Ampulla

6 Mass at uncinate

7 Mass at pancreatic head

8 Area between masses

9 Gallbladder

10 Peripancreatic LNs 6 (F1)

11 Peripancreatic LNs 4 (F2)

12 Peripancreatic LNs 3 (F3)

13 Peripancreatic LNs 2 (F4)

14 Peripancreatic LNs 2 (F5)

15 Peripancreatic LN 1 (F6)

16 Periduodenal LN 1 (F7)

Part G: New pancreatic body margin

1 New pancreatic margin 1

2 New pancreatic margin 2

Source: NCI Genomic Data Commons file 55fb0bd0-f891-4c57-8e1b-d7075013f380 (TCGA-2J-AABO.947FC080-A75D-4D6B-9585-D5204266EF3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).